Somatic mutation profile of tumor specimen TCGA-06-0211-02A (aliquot TCGA-06-0211-02A-02D-2280-08) from TCGA case TCGA-06-0211, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.0 years (17,515 days).
Specimen TCGA-06-0211-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e54a8a3-56ea-4dcf-aa4b-049a7cfd3fba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0211-10A (Blood Derived Normal), aliquot TCGA-06-0211-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14824f7a-b8c6-4f81-9bd9-8068e4e1314d

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 4, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETBP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 82/233 reads (35%) | catalogued as rs1568234874, COSV56319931; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRD1 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as rs747288448, COSV55439743, COSV55456566; called by muse, mutect2, varscan2
- ADH7 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs757367262, COSV52921077; called by muse, mutect2, varscan2
- AMDHD1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758223660, COSV57137813; called by muse, mutect2, varscan2
- CFAP47 | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV52885248; called by muse, mutect2, varscan2
- COL1A2 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749509413, COSV51956332; called by muse, mutect2, varscan2
- CSMD1 | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68209616; called by muse, mutect2, varscan2
- CYP27B1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1028387024, CM1110437, COSV56985373, COSV56986329; called by muse, mutect2, varscan2
- DPT | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.799); catalogued as rs200956999; called by muse, mutect2, varscan2
- GABBR2 | c.1563C>G p.N521K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52305340; called by muse, mutect2, varscan2
- GLT8D2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.271); catalogued as rs373952967; called by muse, mutect2, varscan2
- GRM6 | c.1471G>C p.G491R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51442738; called by muse, mutect2, varscan2
- IQSEC3 | c.2839C>A p.P947T (on ENST00000538872 / NM_001170738.2; = p.P644T on NM_015232.1) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV58285440; called by muse, mutect2, varscan2
- ITSN1 | c.2319G>A p.W773* | Nonsense Mutation (SNP) | VAF 53/172 reads (31%) | catalogued as COSV66083475; called by muse, mutect2, varscan2
- L3MBTL1 | c.2187T>A p.D729E (on ENST00000418998 / NM_001377303.1; = p.D639E on NM_015478.7) | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV64228665; called by muse, mutect2, varscan2
- LDLRAD2 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as COSV60828456; called by muse, mutect2, varscan2
- MAGEB1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs113819941, COSV66775289; called by muse, mutect2, varscan2
- MMP3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs782643785, COSV55406397; called by muse, mutect2, varscan2
- MUC16 | c.42245C>T p.T14082I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as COSV66692528; called by muse, mutect2, varscan2
- MYOCD | c.1060T>G p.S354A | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV58504468; called by muse, mutect2, varscan2
- NCOR1 | c.5152C>T p.R1718W | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373216507; called by muse, mutect2, varscan2
- NLRP13 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as rs1489171935, COSV100738434, COSV61622102; called by muse, mutect2, varscan2
- OPRK1 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV55570940; called by muse, mutect2, varscan2
- OR14J1 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs769244586, COSV65845719; called by muse, mutect2, varscan2
- PCDHGB3 | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV53958553; called by muse, mutect2, varscan2
- PODNL1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.184); catalogued as rs1483316106, COSV54307910; called by muse, mutect2, varscan2
- PTER | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as rs370033967; called by muse, mutect2, varscan2
- RAD51AP2 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV67588196; called by muse, mutect2, varscan2
- REG1B | c.71A>G p.E24G | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); catalogued as COSV59305945, COSV59306170; called by muse, mutect2, varscan2
- SETD2 | c.7624G>A p.E2542K | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57438486, COSV57438931, COSV57446878; called by muse, mutect2, varscan2
- SIGLEC10 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.3); catalogued as COSV59482348; called by muse, mutect2, varscan2
- STARD3NL | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV50518531; called by muse, mutect2, varscan2
- SYT16 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs773454309, COSV70856997; called by muse, mutect2, varscan2
- TLR4 | c.1257G>C p.L419F (on ENST00000355622 / NM_138554.5; = p.L379F on NM_003266.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.473); catalogued as COSV62923395; called by muse, mutect2, varscan2
- TMOD3 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as COSV57943989, COSV57945854; called by muse, mutect2, varscan2
- TMTC4 | c.356C>T p.S119F (on ENST00000376234 / NM_001350577.2; = p.S138F on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV60892414; called by muse, mutect2, varscan2
- TRIM29 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.165); catalogued as rs769401812, COSV59280694; called by mutect2, varscan2
- UGT1A1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs370790922; called by muse, varscan2
- YOD1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60006359; called by muse, mutect2, varscan2
- IGKV1D-42 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CLIC5 | c.687G>A p.T229= (on ENST00000185206 / NM_001370649.1; = p.T70= on NM_016929.5) | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as rs1192732085, COSV51759019; called by muse, mutect2, varscan2
- DPP10 | c.1911G>A p.L637= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV59690125; called by muse, mutect2, varscan2
- FLG | c.2889T>C p.S963= | Silent (SNP) | VAF 134/351 reads (38%) | catalogued as COSV64242540; called by muse, mutect2, varscan2
- HCN1 | c.1623T>A p.I541= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV57513650; called by muse, mutect2, varscan2
- HDAC9 | c.2337C>A p.P779= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as COSV67774301; called by muse, mutect2, varscan2
- ITGAM | c.198C>T p.C66= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs369704125, COSV54938777; called by muse, mutect2, varscan2
- KCNQ5 | c.2337C>T p.D779= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs779824484, COSV59661950; called by muse, mutect2, varscan2
- KIR2DL4 | c.1011G>T p.V337= (on ENST00000396284; = p.V263= on NM_001080770.2) | Silent (SNP) | VAF 119/579 reads (21%) | catalogued as COSV58491490; called by muse, mutect2, varscan2
- LILRB5 | c.621G>A p.S207= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs144716655, COSV100300498; called by muse, mutect2, varscan2
- RFX4 | c.1497G>A p.L499= (on ENST00000392842 / NM_213594.3; = p.L405= on NM_032491.6) | Silent (SNP) | VAF 61/180 reads (34%) | catalogued as COSV57576235; called by muse, mutect2, varscan2
- RSPH10B | c.2301C>G p.V767= | Silent (SNP) | VAF 53/509 reads (10%) | catalogued as rs749626793, COSV58074125; called by muse, mutect2, varscan2
- UGT2B4 | c.534C>T p.Y178= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs370531105; called by muse, mutect2, varscan2
- GLOD4 | chr17:782629 del CCAGCACCTGGG | 5'Flank (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- MIR16-1 | n.27A>G | RNA (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2
